FM case AD16619 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas.
https://portal.gdc.cancer.gov/cases/65b51b46-a09f-4f60-95c2-ea48a9b922ed

Male, 72.2 years: Adenocarcinoma, NOS (ICD-O-3 8140/3); specimen biopsied or resected from the colon. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Tumor.
